Somatic mutation profile of tumor specimen MMRF_2767_1_BM_CD138pos (aliquot MMRF_2767_1_BM_CD138pos_T1_KHS5U_L15718) from MMRF case MMRF_2767, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2767_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 795020ca-38b7-4121-bbd0-d0cc15680307.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2767_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2767_1_PB_WBC_C3_KHS5U_L15762; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/517606d0-4d27-463c-8ef9-9d5f7d50a9e4

The open-access MAF lists 104 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 36, Missense Mutation 33, Intron 17, Silent 9, 5'UTR 3, Nonsense Mutation 2, Splice Region 1, 3'Flank 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123083, CM990103; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2B1 | c.2338A>G p.I780V | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV53806721; called by muse, mutect2, varscan2
- CACHD1 | c.3652G>A p.A1218T | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as rs752822263; called by muse, mutect2, varscan2
- DNAH12 | c.4297G>A p.V1433I (on ENST00000351747; = p.V1456I on NM_001366028.2) | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370685075; called by muse, mutect2, varscan2
- GPR158 | c.2614T>C p.S872P | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs768738975; called by muse, mutect2, varscan2
- H2BC17 | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 126/285 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs373878930, COSV58153207; called by muse, mutect2, varscan2
- H4C2 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV55137627, COSV55138037; called by muse, mutect2, varscan2
- KLHL33 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1354607124, COSV60727164; called by muse, mutect2, varscan2
- LTF | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1218707406; called by muse, mutect2, varscan2
- SEMA5A | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as rs1175107971; called by muse, mutect2, varscan2
- TBXA2R | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1268055705; called by muse, mutect2, varscan2
- TDRD15 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1022711321; called by muse, mutect2, varscan2
- YIPF7 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747220881, COSV60656011; called by muse, mutect2
- ABLIM2 | c.326G>T p.C109F | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC015802.6 | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ANKRD13A | c.1265G>C p.R422P | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CACNA1C | c.4169C>A p.T1390N | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2
- CHD7 | c.3511A>G p.T1171A | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- DOCK1 | c.3142A>T p.R1048* | Nonsense Mutation (SNP) | VAF 113/307 reads (37%) | called by muse, mutect2, varscan2
- DSG2 | c.2438G>C p.C813S | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETV1 | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM193A | c.2999G>A p.G1000E | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.5216T>A p.V1739E | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+5A>C | Splice Region (SNP) | VAF 54/134 reads (40%) | called by muse, mutect2
- LATS2 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPK15 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- PLXNB1 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PROZ | c.1065T>A p.S355R | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RSPH3 | c.1051G>A p.E351K (on ENST00000252655; = p.E209K on NM_031924.8) | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SAMHD1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHE | c.1278C>G p.N426K | Missense Mutation (SNP) | VAF 115/321 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- THADA | c.5392G>T p.G1798* | Nonsense Mutation (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- TMEM30B | c.684C>G p.N228K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2
- TMEM39B | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TRRAP | c.9772G>A p.G3258R (on ENST00000359863 / NM_001244580.1; = p.G3229R on NM_003496.3) | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ULK3 | c.1337T>G p.M446R | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- DDX11 | c.1206C>T p.I402= | Silent (SNP) | VAF 56/269 reads (21%) | called by muse, mutect2, varscan2
- DSC3 | c.1407T>G p.P469= | Silent (SNP) | VAF 91/225 reads (40%) | called by muse, mutect2, varscan2
- FGF23 | c.543C>T p.A181= | Silent (SNP) | VAF 10/163 reads (6%) | catalogued as COSV99426515; called by muse, mutect2
- FUT3 | c.843C>T p.Y281= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs765480346, COSV99744216; called by muse, mutect2, varscan2
- IGLV3-1 | c.252C>T p.N84= | Silent (SNP) | VAF 94/128 reads (73%) | catalogued as rs181381534; called by muse, varscan2
- IGLV3-1 | c.336C>T p.S112= | Silent (SNP) | VAF 101/136 reads (74%) | catalogued as rs73880716; called by muse, varscan2
- TAS2R7 | c.765C>T p.T255= | Silent (SNP) | VAF 104/225 reads (46%) | catalogued as rs201824984; called by muse, mutect2, varscan2
- THRAP3 | c.1956A>G p.E652= | Silent (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2
- ZNF534 | c.1302G>A p.T434= (on ENST00000332323 / NM_001143939.3; = p.T421= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/220 reads (35%) | catalogued as rs772300259; called by muse, mutect2, varscan2
- ABI2 | c.*10504A>G | 3'UTR (SNP) | VAF 49/66 reads (74%) | called by muse, mutect2, varscan2
- ACE | c.1921+295C>G | Intron (SNP) | VAF 30/89 reads (34%) | called by muse, mutect2, varscan2
- ACSS3 | c.*1066G>A | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- ACTG2 | c.126+28C>T | Intron (SNP) | VAF 6/125 reads (5%) | called by muse, mutect2
- ADGRL4 | c.*987G>T | 3'UTR (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- AMOTL1 | c.*3765A>G | 3'UTR (SNP) | VAF 32/51 reads (63%) | called by muse, mutect2, varscan2
- BDP1 | c.-51C>T | 5'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as rs567090162; called by muse, mutect2, varscan2
- C12orf29 | c.90+95T>A | Intron (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- CADPS | c.1325+19886G>A | Intron (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- CCNE2 | c.832-928C>G | Intron (SNP) | VAF 66/289 reads (23%) | called by muse, mutect2, varscan2
- CDK5R1 | c.*2416dup | 3'UTR (INS) | VAF 32/80 reads (40%) | catalogued as rs905830287; called by mutect2, varscan2
- CEP104 | c.*3262G>A | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs1284553555; called by muse, mutect2, varscan2
- CHRM2 | chr7:137019513 A>G | 3'Flank (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- COQ4 | chr9:128322611 T>C | 5'Flank (SNP) | VAF 110/255 reads (43%) | called by muse, mutect2, varscan2
- CSNK2A3 | c.-60A>G | 5'UTR (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- CTSO | c.*1652C>T | 3'UTR (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- CYYR1 | c.334+2264A>T | Intron (SNP) | VAF 13/285 reads (5%) | called by muse, mutect2
- DAP | c.*1759T>G | 3'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- DENND5B | c.*1023T>C | 3'UTR (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- DHX36 | c.*911A>C | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-34-1243T>C | Intron (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- DTX2 | c.*93G>C | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.12903-43G>C | Intron (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- EIF4E | c.19-7761dup | Intron (INS) | VAF 31/76 reads (41%) | called by mutect2, varscan2
- FAM76B | c.208-86C>T | Intron (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- FAT4 | c.*647C>T | 3'UTR (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
- FBN1 | c.164+1782A>G | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- FGD4 | c.*558A>T | 3'UTR (SNP) | VAF 50/91 reads (55%) | called by muse, mutect2, varscan2
- FOXJ3 | c.*1199C>T | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs781734798; called by muse, mutect2, varscan2
- GAB4 | c.*741T>A | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- GCNT1 | c.*746A>G | 3'UTR (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- GPNMB | c.541+64T>C | Intron (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- GRIN2A | c.*6574G>C | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+137T>A | Intron (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- HOXB1 | c.578-81G>C | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- IYD | c.*6346G>A | 3'UTR (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- KATNBL1 | c.*569A>C | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- KCTD20 | c.*883G>A | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- KDM5A | c.*58A>T | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- KLHL1 | c.*931G>A | 3'UTR (SNP) | VAF 34/44 reads (77%) | called by muse, mutect2, varscan2
- KRT4 | c.*144C>A | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- LAMC1 | c.*2069T>A | 3'UTR (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- LMLN | c.*837C>A | 3'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2
- LYPD6 | c.*926G>A | 3'UTR (SNP) | VAF 22/60 reads (37%) | called by muse, varscan2
- MAPT | c.*4078_*4079del | 3'UTR (DEL) | VAF 21/53 reads (40%) | called by pindel, varscan2
- MDGA2 | c.*1612C>T | 3'UTR (SNP) | VAF 19/53 reads (36%) | catalogued as COSV100636518; called by muse, mutect2, varscan2
- MXD4 | c.*665G>A | 3'UTR (SNP) | VAF 9/242 reads (4%) | catalogued as rs1211119245; called by muse, mutect2
- NFIA | c.*3620A>C | 3'UTR (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- NIFK | c.*295G>A | 3'UTR (SNP) | VAF 104/291 reads (36%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*14430G>T | 3'UTR (SNP) | VAF 51/127 reads (40%) | called by muse, mutect2, varscan2
- PHF6 | c.*2480A>G | 3'UTR (SNP) | VAF 27/33 reads (82%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*888+90G>A | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- SEMA6A | c.1895-1786T>A | Intron (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- SLC25A40 | c.742-255T>C | Intron (SNP) | VAF 104/273 reads (38%) | called by muse, mutect2, varscan2
- SNORD115-9 | n.18C>T | RNA (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- ST13 | c.*1151A>T | 3'UTR (SNP) | VAF 50/195 reads (26%) | called by muse, mutect2, varscan2
- TMEM82 | c.*303G>T | 3'UTR (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- TPR | c.-43T>A | 5'UTR (SNP) | VAF 96/227 reads (42%) | called by muse, mutect2, varscan2
- TPRG1 | c.*1621del | 3'UTR (DEL) | VAF 49/156 reads (31%) | called by mutect2, pindel, varscan2
